Somatic mutation profile of tumor specimen 01f203fd-e664-4d78-bea0-7c40cf (aliquot 01f203fd-e664-4d78-bea0-7c40cf_D6_1) from CPTAC case 03BR013, project CPTAC-2 (Breast — Ductal and Lobular Neoplasms). Sex at birth: female; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.0 years (19,010 days).
Specimen 01f203fd-e664-4d78-bea0-7c40cf: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 647ae520-c1b8-4963-8d7f-69cadf10eaa0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 24c38c22-1518-40bf-9f39-043d7d (Blood Derived Normal), aliquot 24c38c22-1518-40bf-9f39-043d7d_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9f1830a2-eca9-43f5-b05a-83eb113391c2

The open-access MAF lists 45 somatic variants for this specimen: 25 protein-altering or splice-affecting, 14 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 14, RNA 2, Nonsense Mutation 2, 3'UTR 1, Frame Shift Del 1, Intron 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TRIOBP | c.4130G>A p.W1377* | Nonsense Mutation (SNP) | VAF 46/519 reads (9%) | catalogued as rs747619979, COSV60375169; ClinVar: likely pathogenic; called by muse, mutect2
- B4GALNT4 | c.379G>A p.E127K | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs957171308; called by muse, mutect2
- CACNA1I | c.4816C>T p.R1606W | Missense Mutation (SNP) | VAF 48/160 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747847066; called by muse, mutect2, varscan2
- CFAP298 | c.809C>T p.A270V | Missense Mutation (SNP) | VAF 13/303 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as rs990901874, COSV51592295; called by muse, mutect2
- FABP1 | c.371G>T p.S124I | Missense Mutation (SNP) | VAF 22/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV55557816, COSV99860995; called by muse, mutect2, varscan2
- ITGA1 | c.1948G>A p.D650N | Missense Mutation (SNP) | VAF 17/184 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99252109; called by muse, mutect2
- KPNA1 | c.73C>T p.R25C | Missense Mutation (SNP) | VAF 22/253 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1398957671; called by muse, mutect2
- LCP2 | c.12G>T p.R4S | Missense Mutation (SNP) | VAF 82/268 reads (31%) | SIFT tolerated (0.1); PolyPhen benign (0.001); catalogued as rs1425685889, COSV50451471; called by muse, varscan2
- MAP4K4 | c.2485C>T p.P829S (on ENST00000347699 / NM_001242559.2; = p.P747S on NM_004834.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 21/184 reads (11%) | SIFT tolerated, low confidence (0.25); PolyPhen probably damaging (0.998); catalogued as COSV56334880; called by muse, mutect2, varscan2
- SLC18A3 | c.725G>A p.R242H | Missense Mutation (SNP) | VAF 37/286 reads (13%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as rs1371247153; called by muse, mutect2, varscan2
- WNT3A | c.422G>A p.R141H | Missense Mutation (SNP) | VAF 39/285 reads (14%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as rs148616293; called by muse, mutect2, varscan2
- XIRP2 | c.6623C>A p.S2208Y (on ENST00000628543; = p.S2383Y on NM_152381.6) | Missense Mutation (SNP) | VAF 121/325 reads (37%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.182); catalogued as COSV54681034; called by muse, mutect2, varscan2
- C16orf96 | c.3089G>T p.R1030L | Missense Mutation (SNP) | VAF 70/199 reads (35%) | SIFT tolerated (0.31); PolyPhen benign (0.001); called by muse, varscan2
- C1orf112 | c.785A>C p.E262A | Missense Mutation (SNP) | VAF 52/188 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); called by muse, mutect2, varscan2
- CAMSAP2 | c.3398C>A p.P1133H (on ENST00000236925 / NM_001297707.2; = p.P1122H on NM_203459.3) | Missense Mutation (SNP) | VAF 169/339 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- CDC42BPA | c.3113G>T p.R1038I (on ENST00000334218 / NM_001366019.2; = p.R1025I on NM_003607.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 14/250 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CLTB | c.373del p.E125Nfs*23 | Frame Shift Del (DEL) | VAF 23/148 reads (16%) | called by mutect2, varscan2
- FBRSL1 | c.736A>T p.K246* | Nonsense Mutation (SNP) | VAF 6/42 reads (14%) | called by muse, varscan2
- LARP4 | c.8T>A p.L3H | Missense Mutation (SNP) | VAF 12/218 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.602); called by muse, mutect2
- LDB3 | c.1003C>T p.P335S | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT tolerated (0.8); PolyPhen benign (0.001); called by muse, mutect2
- NDUFAF1 | c.53C>G p.S18C | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0); called by muse, mutect2
- PPFIA1 | c.214G>A p.G72S | Missense Mutation (SNP) | VAF 129/334 reads (39%) | SIFT tolerated (0.7); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- PRKG2 | c.184A>T p.T62S | Missense Mutation (SNP) | VAF 110/334 reads (33%) | SIFT tolerated (0.66); PolyPhen benign (0.01); called by muse, varscan2
- ROCK1 | c.2059G>A p.E687K | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2
- SNAPC4 | c.2860G>A p.G954R | Missense Mutation (SNP) | VAF 57/234 reads (24%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.97); called by muse, mutect2, varscan2
- AL162231.1 | c.171C>T p.S57= | Silent (SNP) | VAF 4/20 reads (20%) | called by muse, mutect2
- ANKEF1 | c.2256C>T p.F752= | Silent (SNP) | VAF 20/340 reads (6%) | catalogued as rs776549053, COSV65692232, COSV65692775; called by muse, mutect2
- ARMCX5-GPRASP2 | c.1134C>A p.S378= | Silent (SNP) | VAF 103/372 reads (28%) | called by muse, mutect2, varscan2
- COL7A1 | c.8571G>A p.E2857= | Silent (SNP) | VAF 90/369 reads (24%) | called by muse, mutect2, varscan2
- DYRK1A | c.225C>T p.V75= | Silent (SNP) | VAF 15/112 reads (13%) | called by muse, mutect2, varscan2
- GPATCH1 | c.1548C>T p.Y516= | Silent (SNP) | VAF 21/209 reads (10%) | catalogued as rs771567388; called by muse, mutect2, varscan2
- ITGB4 | c.4356G>A p.P1452= | Silent (SNP) | VAF 66/251 reads (26%) | catalogued as rs765826823; called by muse, mutect2, varscan2
- MTMR6 | c.690C>G p.V230= | Silent (SNP) | VAF 14/185 reads (8%) | called by muse, mutect2
- NPAS3 | c.2601G>A p.T867= (on ENST00000356141 / NM_001164749.2; = p.T835= on NM_022123.3) | Silent (SNP) | VAF 49/238 reads (21%) | catalogued as rs1200113406; called by muse, mutect2, varscan2
- PCDHGA6 | c.180G>A p.A60= | Silent (SNP) | VAF 54/293 reads (18%) | catalogued as COSV53989788; called by muse, mutect2, varscan2
- PLEKHG1 | c.1680G>A p.Q560= | Silent (SNP) | VAF 37/229 reads (16%) | called by muse, mutect2, varscan2
- POR | c.1689G>A p.T563= | Silent (SNP) | VAF 8/146 reads (5%) | catalogued as rs781819761; called by muse, mutect2
- RYR2 | c.5271C>T p.L1757= | Silent (SNP) | VAF 36/496 reads (7%) | catalogued as COSV63684757; called by muse, mutect2
- TBX22 | c.675C>T p.H225= | Silent (SNP) | VAF 107/338 reads (32%) | catalogued as rs770012858, COSV100960908; called by muse, mutect2, varscan2
- C5orf60 | n.1903C>T | RNA (SNP) | VAF 89/325 reads (27%) | called by muse, mutect2, varscan2
- CD46 | c.*157A>G | 3'UTR (SNP) | VAF 47/481 reads (10%) | called by muse, mutect2, varscan2
- MUC19 | chr12:40545959 C>T | 3'Flank (SNP) | VAF 18/224 reads (8%) | called by muse, mutect2
- PSENEN | c.-34C>T | 5'UTR (SNP) | VAF 101/300 reads (34%) | catalogued as rs1288799687; called by muse, mutect2, varscan2
- SRGAP2D | n.95G>A | RNA (SNP) | VAF 26/510 reads (5%) | called by muse, mutect2
- SYT7 | c.215+8828C>T | Intron (SNP) | VAF 10/24 reads (42%) | catalogued as rs1442496618; called by muse, varscan2
